RC case RC-B5DD — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef7fb12a-09ec-49f9-ade4-96d7da54e0f3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1932; Vital status: Dead; Days to death: 119 days; Year of death: 2014.

Diagnoses (1)
1. Extranodal NK/T-cell lymphoma, nasal type: ICD-O-3 morphology code: 9719/3; ICD-10 code: C84; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 81.4 years (29,732 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Weight Loss; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Sinus / Skin.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, NOS.

Follow-up (1 entry)
- Days to follow up: 119 days; Disease response: With Tumor.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Positive.
- Epstein-Barr Virus: Negative [Test analyte type: DNA].
- Lactate Dehydrogenase 214 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Congestive Heart Failure (CHF) / Coronary Artery Disease / Diabetes, NOS / Heart Disease / Ventricular Tachycardia / Peripheral Vascular Disease / Glaucoma / Cataracts.
- Timepoint category: Initial Diagnosis; Weight: 77.7 kg; Height: 174 cm; BMI: 25.7.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5DD-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5DD-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B5DD-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
